Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2NG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2NG-06A (Metastatic).

**ADDENDA:
Addendum**

Collection Date:

MOLECULAR ANATOMIC PATHOLOGY TESTING:

BRAF mutation IDENTIFIED

NOTE:

The quantity and quality of the isolated DNA was acceptable for testing.

FINAL DIAGNOSIS:

**PART 1: SKIN, RIGHT AXILLARY SCAR, EXCISION -
SCAR AND SUTURE GRANULOMA IN DERMIS. NO TUMOR SEEN.**

**PART 2: RIGHT AXILLARY LYMPH NODE, RESECTION -
A. METASTATIC MELANOMA IN TWELVE OUT OF TWELVE LYMPH NODES.
B. EXTRACAPSULAR SPREAD PRESENT.
C. LARGEST LYMPH NODE 4.5 CM.**

**COMMENT:
BRAF ordered**

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, Axillary

C77.3

hw
8/19/11

hw 8/19/11

Source: NCI Genomic Data Commons file b09eef3e-a672-4f11-b575-8fd99cbbd751 (TCGA-ER-A2NG.31E2C9E4-8AE8-4303-9440-DC608E8ED9A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).